Somatic mutation profile of tumor specimen TCGA-IB-7890-01A (aliquot TCGA-IB-7890-01A-12D-2201-08) from TCGA case TCGA-IB-7890, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,747 days).
Specimen TCGA-IB-7890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8323e9cc-8ca7-4edc-8a0e-19523bc048cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7890-10A (Blood Derived Normal), aliquot TCGA-IB-7890-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/755607a3-3fb2-40b8-979c-8445eaa8b1a7

The open-access MAF lists 67 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 45, Silent 17, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 146/496 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 115/323 reads (36%) | catalogued as rs1567551821, COSV52710769, COSV52715098, COSV52760685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs532653294, COSV100178411; called by muse, mutect2, varscan2
- ATAD5 | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 79/566 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs764586127, COSV100430213; called by muse, mutect2, varscan2
- AXIN1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 398/1758 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs750185512, COSV51989084; called by muse, mutect2, varscan2
- BFAR | c.773G>C p.W258S | Missense Mutation (SNP) | VAF 132/489 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99902454; called by muse, mutect2, varscan2
- BUB1 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 143/969 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100241651; called by muse, mutect2, varscan2
- CCDC39 | c.2618A>C p.K873T | Missense Mutation (SNP) | VAF 138/360 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV99870607; called by muse, mutect2, varscan2
- CDC42 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 90/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100212689; called by muse, mutect2, varscan2
- CELF6 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760379153, COSV54718562; called by muse, mutect2, varscan2
- COL27A1 | c.4694G>A p.G1565D | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621320; called by muse, mutect2, varscan2
- CORO2B | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs371239183; called by muse, mutect2, varscan2
- DCAF17 | c.1034T>A p.I345N | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100266384; called by muse, mutect2, varscan2
- DNMBP | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV100144407; called by muse, mutect2, varscan2
- EED | c.467G>C p.S156T | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99646606; called by muse, mutect2, varscan2
- EPB42 | c.1124C>T p.T375M (on ENST00000441366 / NM_001114134.2; = p.T405M on NM_000119.3) | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs115972761, COSV55748610; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPPK1 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 82/764 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782491999, COSV101599951; called by muse, mutect2, varscan2
- ESAM | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs759294805, COSV99631714, COSV99632052; called by muse, mutect2, varscan2
- FAM83H | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | catalogued as COSV100568096; called by muse, mutect2, varscan2
- FBXW5 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs1402005933, COSV99812680; called by muse, mutect2, varscan2
- FURIN | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 120/740 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV99076033, COSV99184791; called by muse, mutect2, varscan2
- GAD1 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs769110394, COSV100713927; called by muse, mutect2, varscan2
- GCM2 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 38/241 reads (16%) | catalogued as rs1471945273, COSV101069620; called by muse, mutect2, varscan2
- GLB1 | c.1915G>A p.V639M | Missense Mutation (SNP) | VAF 81/512 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as rs1222326938, COSV100257687; called by muse, mutect2, varscan2
- GLMN | c.821T>C p.F274S | Missense Mutation (SNP) | VAF 87/459 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV100950196; called by muse, mutect2, varscan2
- GPAT3 | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 201/766 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100023287; called by muse, varscan2
- GPR151 | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 105/785 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99695278; called by muse, mutect2, varscan2
- GPX5 | c.37del p.L13Ffs*3 | Frame Shift Del (DEL) | VAF 159/1101 reads (14%) | catalogued as COSV69079256, COSV69079803; called by mutect2, pindel, varscan2
- GUCY2F | c.2558C>T p.T853M | Missense Mutation (SNP) | VAF 118/380 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs781268860, COSV54298486; called by muse, mutect2, varscan2
- HEXIM1 | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 276/828 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755261268, COSV100203593; called by muse, mutect2, varscan2
- IGHA1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs375842678; called by muse, varscan2
- IGSF10 | c.6469G>T p.D2157Y | Missense Mutation (SNP) | VAF 73/556 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99194527; called by muse, mutect2, varscan2
- LCP1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 106/782 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59939531; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 52/1274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2
- MUC16 | c.17114C>T p.A5705V | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs200898366; called by muse, mutect2, varscan2
- NTF3 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100451155; called by muse, mutect2, varscan2
- OR52K2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 107/678 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs750840213, COSV57835623; called by muse, mutect2, varscan2
- PCDHGA6 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as rs1211342702, COSV53899875; called by muse, mutect2, varscan2
- PKDCC | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV99684995; called by muse, mutect2, varscan2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2, varscan2
- SERPINA3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 135/865 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs752346883, COSV67587323; called by muse, mutect2, varscan2
- SIK3 | c.2824C>T p.R942W (on ENST00000445177 / NM_001366686.2; = p.R900W on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/770 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs767005637, COSV99408808; called by muse, mutect2, varscan2
- SLC6A4 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 179/557 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99911594; called by muse, mutect2, varscan2
- SLC8A3 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201527251, COSV100776371; called by muse, mutect2, varscan2
- SRPK1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100644453, COSV60416623; called by muse, mutect2, varscan2
- TCN2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs1258577765, COSV53192497; called by muse, mutect2, varscan2
- TMEM151A | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV100517070; called by muse, mutect2
- ZFHX3 | c.6164C>T p.P2055L | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs144401383; called by muse, mutect2, varscan2
- ZNF385D | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs775396986, COSV99876395; called by muse, mutect2, varscan2
- PRSS1 | c.669_671del p.K223del | In Frame Del (DEL) | VAF 63/506 reads (12%) | called by pindel, varscan2
- ADGRV1 | c.5616T>C p.F1872= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as COSV101316491; called by muse, mutect2, varscan2
- ALMS1 | c.2262T>C p.T754= | Silent (SNP) | VAF 161/1263 reads (13%) | catalogued as COSV100043679; called by muse, mutect2, varscan2
- CIAO1 | c.252C>T p.T84= | Silent (SNP) | VAF 151/591 reads (26%) | catalogued as rs1206971254, COSV99302743; called by muse, mutect2, varscan2
- EPB41L3 | c.2025C>T p.S675= | Silent (SNP) | VAF 85/351 reads (24%) | catalogued as rs1391239130, COSV100548238; called by muse, mutect2, varscan2
- FMN2 | c.2013A>G p.G671= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as rs568308648, COSV100147078, COSV60422808; called by muse, mutect2, varscan2
- GZMM | c.108G>A p.S36= | Silent (SNP) | VAF 34/704 reads (5%) | catalogued as rs776715218, COSV99198873; called by muse, mutect2
- KATNB1 | c.1908G>A p.L636= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101109353; called by muse, mutect2
- NMT1 | c.624C>A p.P208= | Silent (SNP) | VAF 100/740 reads (14%) | catalogued as COSV99364992; called by muse, mutect2, varscan2
- NRSN1 | c.474C>T p.I158= | Silent (SNP) | VAF 49/311 reads (16%) | catalogued as rs779334465, COSV65894253; called by muse, mutect2, varscan2
- PTPRS | c.5347C>A p.R1783= | Silent (SNP) | VAF 76/315 reads (24%) | catalogued as COSV99512367; called by muse, mutect2, varscan2
- RBL1 | c.565C>A p.R189= | Silent (SNP) | VAF 45/319 reads (14%) | catalogued as COSV60330270; called by muse, mutect2, varscan2
- RTN3 | c.159C>T p.S53= | Silent (SNP) | VAF 139/591 reads (24%) | catalogued as rs781616672, COSV100127511; called by muse, mutect2, varscan2
- TMTC4 | c.897C>T p.T299= (on ENST00000376234 / NM_001350577.2; = p.T318= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 190/617 reads (31%) | catalogued as rs529835816, COSV100168950, COSV60893038; called by muse, mutect2, varscan2
- UNC79 | c.6342G>A p.S2114= (on ENST00000393151 / NM_001346218.2; = p.S1937= on NM_020818.5) | Silent (SNP) | VAF 164/972 reads (17%) | catalogued as rs777508770, COSV56414030; called by muse, mutect2, varscan2
- XYLT2 | c.2001G>A p.G667= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as COSV99191134; called by muse, mutect2, varscan2
- ZNF804A | c.1206A>G p.S402= | Silent (SNP) | VAF 58/457 reads (13%) | catalogued as COSV100170143; called by muse, mutect2, varscan2
- ZNF831 | c.3474G>A p.T1158= | Silent (SNP) | VAF 99/644 reads (15%) | catalogued as rs767673212, COSV64038612; called by muse, mutect2, varscan2
